ALCHEMIST case ALCH-B2A4 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/85eeb672-2a11-45a6-94a1-36e39ec5b153

Demographics
Sex at birth: male.

Diagnoses (1)
1. Large cell carcinoma, NOS: Age at diagnosis: 73.2 years (26,750 days).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2A4-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2A4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2A4-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 23; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 6; Percent neutrophil infiltration: 5.
- Sample ALCH-B2A4-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2A4-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 20; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
